Somatic mutation profile of tumor specimen BA2357D (aliquot aq-BA2357D) from BEATAML1.0 case 2245, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,258 days).
Specimen BA2357D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c7aa843-4082-469e-8754-2cdcc731f745.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2706D (Solid Tissue Normal), aliquot aq-BA2706D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4c9e8cc-2181-4ed8-903d-71901be3eeab

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.521G>A p.R174Q (on ENST00000344691 / NM_001001890.3; = p.R201Q on NM_001754.5) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs74315450, CM992140, COSV55867719, COSV55890900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1330105689; called by muse, mutect2
- KDM5C | c.4442G>A p.R1481K | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as CD086101; called by muse, mutect2, varscan2
- MAP2K7 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs942074295, COSV67607842; called by muse, mutect2
- MED13 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101181340; called by muse, mutect2, varscan2
- NCKAP1L | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180951280; called by muse, mutect2, varscan2
- PRAMEF4 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs375310027; called by muse, mutect2, varscan2
- STAG2 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54349782; called by muse, mutect2, varscan2
- TIAM1 | c.3654C>T p.D1218= | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as rs375189386; called by muse, mutect2, varscan2
- CAD | c.4975G>A p.E1659K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL5A3 | c.2506G>A p.G836S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCC1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- NOS1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK5 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- ZNF234 | c.1835A>C p.Q612P | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NIBAN1 | c.732G>A p.L244= | Silent (SNP) | VAF 48/108 reads (44%) | called by muse, varscan2
- TAF1C | c.1311T>G p.R437= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- STXBP2 | c.902+27C>T | Intron (SNP) | VAF 33/81 reads (41%) | catalogued as rs1378303293; called by muse, mutect2, varscan2
